CPTAC case C3L-04036 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cab6920d-01dc-4afc-a038-0a4a751abb85

Demographics
Sex at birth: male; Race: white; Year of birth: 1937; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 81.2 years (29,658 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 1,391 days (3.8 years); Days to last follow up: 1,391 days (3.8 years).
   Pathology details: Greatest tumor dimension: 5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (5 entries)
- Days to follow up: 497 days (1.4 years); Disease response: With Tumor; ECOG performance status: 3.
- Days to follow up: 756 days (2.1 years); Disease response: With Tumor; ECOG performance status: 2.
- Days to follow up: 978 days (2.7 years); Disease response: With Tumor; ECOG performance status: 2.
- Days to follow up: 978 days (2.7 years); Disease response: Progressive Disease; ECOG performance status: 2.
- Days to follow up: 1,391 days (3.8 years); Disease response: With Tumor; ECOG performance status: 2.

Other clinical attributes
- Weight: 70 kg; Height: 180 cm; BMI: 21.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-04036-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 1,189 mg; Time between excision and freezing: 20 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-04036-21: Section location: Temporal Lobe; Percent tumor nuclei: 60; Percent necrosis: 7.
- Sample C3L-04036-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
